Somatic mutation profile of tumor specimen C3N-00498-02 (aliquot CPT0013000010) from CPTAC case C3N-00498, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.3 years (23,112 days).
Specimen C3N-00498-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8f5b4cd-6b3b-49db-b735-8b5153df5de3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00498-31 (Blood Derived Normal), aliquot CPT0013090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fad103da-656c-4123-bbe0-f49594724bb5

The open-access MAF lists 187 somatic variants for this specimen: 127 protein-altering or splice-affecting, 44 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 44, Intron 10, Nonsense Mutation 8, Frame Shift Ins 5, Frame Shift Del 4, RNA 3, Splice Site 3, Splice Region 2, 3'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEXMIF | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs886041701, COSV50111243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 177/458 reads (39%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATG16L1 | c.901C>G p.H301D (on ENST00000392017 / NM_030803.7; = p.H282D on NM_017974.4) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV100731200; called by muse, mutect2, varscan2
- ATP6V1G3 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99811041; called by muse, mutect2, varscan2
- BCL9L | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52687466; called by muse, mutect2, varscan2
- CNTN2 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753710924, COSV59348323; called by muse, mutect2, varscan2
- COL2A1 | c.1833+1G>A p.X611_splice | Splice Site (SNP) | VAF 24/352 reads (7%) | catalogued as CS000216, COSV61533848; called by muse, mutect2
- CYP2C18 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs755901390, COSV53670548; called by muse, mutect2, varscan2
- DMD | c.6583G>T p.V2195F | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1427091707; called by muse, mutect2, varscan2
- DNAH5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV54239692; called by muse, mutect2
- DST | c.14665C>T p.H4889Y (on ENST00000361203 / NM_001374722.1; = p.H2477Y on NM_015548.5) | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs1412737238; called by muse, mutect2
- ELN | c.2218C>T p.P740S (on ENST00000320399 / NM_001278939.1; = p.P707S on NM_000501.4) | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52711987; called by muse, mutect2
- FBLN2 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs111284875, CM1211793, COSV99852412; called by muse, mutect2, varscan2
- FNTB | c.1065C>A p.G355= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as rs148608658; called by muse, varscan2
- FRY | c.4759G>C p.D1587H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV66570407; called by muse, mutect2
- GABRR2 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1562358164, COSV68765703; called by muse, mutect2, varscan2
- GNAS | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as COSV55682862; called by muse, mutect2
- GRIN2A | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV58045396; called by muse, mutect2
- GRSF1 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.125); catalogued as COSV99636190; called by muse, mutect2
- GRXCR1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1264434684; called by muse, mutect2, varscan2
- GULP1 | c.629A>T p.K210M | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63065267; called by muse, mutect2
- KCNK12 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as rs1447996540, COSV59946656; called by muse, mutect2
- LTBP4 | c.2186C>A p.T729K (on ENST00000308370 / NM_001042544.1; = p.T692K on NM_003573.2) | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99199277; called by muse, varscan2
- MARS2 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as rs199761896; called by muse, mutect2, varscan2
- MOB4 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as rs766989588; called by muse, mutect2, varscan2
- MROH1 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1200107487; called by muse, mutect2, varscan2
- MYH7B | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1219451170, COSV53420883; called by muse, mutect2
- NMS | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1171102476, COSV65258591; called by muse, mutect2, varscan2
- NOTCH2 | c.3607A>G p.I1203V | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1553195628; called by muse, mutect2, varscan2
- NPTXR | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.068); catalogued as COSV60728261; called by muse, mutect2, varscan2
- NRXN1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as rs201966126, COSV101277659, COSV68003819; called by muse, mutect2, varscan2
- OR13A1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs777258483, COSV65572247; called by muse, mutect2, varscan2
- OR5L2 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.642); catalogued as COSV65723774; called by muse, mutect2, varscan2
- OXR1 | c.210G>T p.R70S (on ENST00000442977 / NM_001198532.1; = p.R69S on NM_018002.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1337582877; called by muse, varscan2
- P4HB | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 24/541 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776010531, COSV100515951; called by muse, mutect2
- PAPSS1 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV54488634; called by muse, mutect2, varscan2
- PCOLCE | c.133T>A p.S45T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV53827661; called by muse, mutect2, varscan2
- PNPLA1 | c.704C>T p.P235L (on ENST00000394571 / NM_001374623.1; = p.P140L on NM_173676.2) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs376245108; called by muse, mutect2
- PRMT8 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54212047; called by muse, mutect2, varscan2
- RCC1L | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs140417187, COSV57319988; called by muse, mutect2, varscan2
- SEMA3E | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV57096393; called by muse, mutect2, varscan2
- SP140 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100613595; called by muse, mutect2
- SRCAP | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52681362; called by muse, mutect2, varscan2
- TAS2R14 | c.589A>G p.M197V | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs371442905; called by muse, mutect2, varscan2
- TIGAR | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1167833273, COSV51627992; called by muse, mutect2
- TRAV13-1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751141340; called by muse, mutect2, varscan2
- TREM1 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 73/180 reads (41%) | catalogued as COSV55147915; called by muse, mutect2, varscan2
- TTC6 | c.913A>G p.T305A (on ENST00000267368; = p.T1671A on NM_001310135.3) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1256446586; called by muse, mutect2
- ZMYND8 | c.319C>T p.P107S (on ENST00000311275 / NM_001363741.2; = p.P127S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53696734; called by muse, mutect2
- ZNF835 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV101606233, COSV73379348; called by muse, mutect2
- ZSCAN12 | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV104417989; called by muse, mutect2, varscan2
- ADAM15 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 12/359 reads (3%) | called by muse, mutect2
- ALX1 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2, varscan2
- AMPD1 | c.1488-6C>T | Splice Region (SNP) | VAF 116/264 reads (44%) | called by muse, mutect2, varscan2
- ARAP2 | c.2810A>T p.D937V | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- BICRA | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- C4BPB | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- CCDC168 | c.15312G>C p.Q5104H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2
- CCDC178 | c.1963G>C p.E655Q (on ENST00000383096 / NM_001105528.3; = p.E617Q on NM_198995.3) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CCDC18 | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CHD2 | c.4137+2T>C p.X1379_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- CLNK | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- COL3A1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.014); called by muse, mutect2
- CST5 | c.353T>A p.F118Y | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CUL1 | c.732dup p.T245Yfs*6 | Frame Shift Ins (INS) | VAF 29/163 reads (18%) | called by mutect2, pindel, varscan2
- CUL4B | c.2602C>T p.L868F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DIAPH1 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAL1 | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DPP6 | c.2383dup p.I795Nfs*15 (on ENST00000377770 / NM_001364500.2; = p.I733Nfs*15 on NM_001936.5) | Frame Shift Ins (INS) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- DROSHA | c.2734C>G p.H912D | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EIF5B | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ESYT2 | c.376G>T p.V126L (on ENST00000613624; = p.V50L on NM_020728.3) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- FAM47B | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- FAT1 | c.11084del p.L3695Yfs*4 | Frame Shift Del (DEL) | VAF 69/235 reads (29%) | called by mutect2, pindel, varscan2
- FBN1 | c.5530A>C p.T1844P | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- FRMD3 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GOLM1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- GPR119 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- HAUS6 | c.828dup p.P277Sfs*6 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- HMBS | c.935del p.D312Afs*5 | Frame Shift Del (DEL) | VAF 105/383 reads (27%) | called by mutect2, pindel, varscan2
- KEAP1 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF13B | c.3859A>G p.K1287E | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- KIF4B | c.1934A>G p.N645S | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.8653C>T p.Q2885* | Nonsense Mutation (SNP) | VAF 114/386 reads (30%) | called by muse, mutect2, varscan2
- LRRK1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LZIC | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MAPT | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- MED13L | c.5609C>G p.S1870C | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMUT | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); called by muse, mutect2
- MYBL1 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- NBEAL1 | c.6947T>A p.I2316K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); called by muse, varscan2
- NEK6 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NYAP2 | c.538A>T p.R180* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | called by muse, varscan2
- OR10G8 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR11H12 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- OR4C15 | c.745G>C p.G249R (on ENST00000314644; = p.G195R on NM_001001920.2) | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.315); called by muse, mutect2
- OTOGL | c.5112T>A p.N1704K (on ENST00000547103; = p.N1695K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, varscan2
- PAK6 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAN3 | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PCDHB9 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PGK2 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2A | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PPP1R12C | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRTG | c.597T>A p.D199E | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRK | c.1575+2T>C p.X525_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- RAB40AL | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RABGGTB | c.98_110del p.K33Mfs*9 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- RIC1 | c.4250dup p.Y1418Lfs*29 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- RLN2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 76/120 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- RP1 | c.214A>T p.R72W | Missense Mutation (SNP) | VAF 100/411 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RPA3 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 66/200 reads (33%) | called by muse, mutect2, varscan2
- RPL6 | c.683A>C p.Q228P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- SCAF4 | c.2642dup p.M881Ifs*37 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- SLAMF1 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); called by muse, mutect2
- SLC24A5 | c.990G>C p.W330C | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.3924C>G p.D1308E (on ENST00000367255 / NM_182961.4; = p.D1315E on NM_033071.3) | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNGAP1 | c.904T>G p.S302A | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.2474G>A p.S825N | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2
- TNFAIP2 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, varscan2
- TNS3 | c.4276C>T p.P1426S | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM42 | c.2070G>C p.W690C | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2
- WDR24 | c.1593G>C p.E531D (on ENST00000248142; = p.E401D on NM_032259.4) | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.316); called by muse, mutect2
- WDR49 | c.1617G>C p.E539D (on ENST00000308378 / NM_001366158.1; = p.E880D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZIC1 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF544 | c.1616A>G p.Q539R | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ZNF658 | c.1079A>T p.D360V | Missense Mutation (SNP) | VAF 133/488 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF711 | c.637del p.E213Kfs*3 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- ADAM2 | c.171T>A p.T57= | Silent (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.879C>A p.T293= | Silent (SNP) | VAF 65/147 reads (44%) | called by muse, mutect2, varscan2
- ADAT3 | c.636G>T p.G212= | Silent (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- AMOTL2 | c.1428G>A p.L476= | Silent (SNP) | VAF 83/356 reads (23%) | catalogued as rs1344050807; called by muse, mutect2, varscan2
- ANK3 | c.11316C>T p.G3772= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs770252457, COSV55055434; called by muse, mutect2, varscan2
- CALHM6 | c.393C>T p.S131= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- CCDC168 | c.11520G>A p.T3840= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as rs775110419; called by muse, mutect2, varscan2
- CERKL | c.906C>T p.T302= (on ENST00000339098 / NM_001030311.2; = p.T276= on NM_201548.5) | Silent (SNP) | VAF 9/280 reads (3%) | catalogued as COSV100182840; called by muse, mutect2
- CHCHD3 | c.354T>G p.A118= | Silent (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- CR2 | c.2379C>G p.V793= | Silent (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- EPHA4 | c.2166G>A p.Q722= | Silent (SNP) | VAF 60/238 reads (25%) | catalogued as rs778991917; called by muse, mutect2, varscan2
- FAM91A1 | c.2367C>A p.P789= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- FANCF | c.492G>A p.K164= | Silent (SNP) | VAF 25/372 reads (7%) | called by muse, mutect2
- FAXC | c.732C>G p.R244= | Silent (SNP) | VAF 55/261 reads (21%) | catalogued as COSV67601718; called by muse, mutect2, varscan2
- FKBPL | c.210T>C p.V70= | Silent (SNP) | VAF 28/558 reads (5%) | called by muse, mutect2
- GBX2 | c.954C>T p.S318= | Silent (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- GIGYF2 | c.3339G>A p.K1113= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- GIPR | c.777C>T p.Y259= | Silent (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- HERC2 | c.6408C>T p.A2136= | Silent (SNP) | VAF 141/479 reads (29%) | called by muse, mutect2, varscan2
- INTS1 | c.2808G>A p.Q936= | Silent (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- KCNH7 | c.198C>T p.C66= | Silent (SNP) | VAF 63/241 reads (26%) | catalogued as rs368853485, COSV59790126; called by muse, mutect2, varscan2
- KCNK4 | c.718C>T p.L240= | Silent (SNP) | VAF 13/246 reads (5%) | catalogued as rs1180041177; called by muse, mutect2
- KIAA0408 | c.303G>A p.L101= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV100846977; called by muse, mutect2, varscan2
- KRTAP2-4 | c.165C>T p.C55= | Silent (SNP) | VAF 6/194 reads (3%) | catalogued as rs1340733978; called by muse, mutect2
- LAMA2 | c.2400C>G p.T800= | Silent (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- LRRC20 | c.24C>A p.A8= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs371622456; called by muse, mutect2, varscan2
- LYPD6B | c.537G>T p.V179= (on ENST00000409029 / NM_001317004.1; = p.V203= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- NLRP3 | c.195G>A p.A65= | Silent (SNP) | VAF 36/532 reads (7%) | catalogued as rs201205620; ClinVar: likely benign; called by muse, mutect2
- OR10G7 | c.130C>T p.L44= | Silent (SNP) | VAF 42/258 reads (16%) | called by muse, mutect2, varscan2
- PCDH17 | c.291C>A p.R97= | Silent (SNP) | VAF 166/378 reads (44%) | called by muse, mutect2, varscan2
- PRR29 | c.372G>T p.L124= | Silent (SNP) | VAF 56/215 reads (26%) | called by muse, mutect2, varscan2
- PSD4 | c.2178G>C p.L726= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- RBM47 | c.657C>A p.I219= | Silent (SNP) | VAF 78/209 reads (37%) | catalogued as COSV55943768; called by muse, mutect2, varscan2
- RHO | c.972C>T p.G324= | Silent (SNP) | VAF 169/508 reads (33%) | called by muse, mutect2, varscan2
- RIBC2 | c.1053C>T p.A351= | Silent (SNP) | VAF 8/236 reads (3%) | called by muse, mutect2
- SH2D3C | c.423T>G p.P141= | Silent (SNP) | VAF 67/207 reads (32%) | called by muse, mutect2, varscan2
- SLC35D2 | c.867T>C p.G289= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- SLC43A2 | c.567C>T p.S189= | Silent (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- TAS2R60 | c.582C>G p.L194= | Silent (SNP) | VAF 17/303 reads (6%) | called by muse, mutect2
- TECTA | c.5304G>C p.A1768= | Silent (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- TGM7 | c.1797C>T p.V599= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs1411488542; called by muse, mutect2, varscan2
- TMPRSS13 | c.957G>C p.L319= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2
- USH2A | c.123G>A p.E41= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV56407748; called by muse, mutect2, varscan2
- ZBTB22 | c.1719G>A p.G573= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- APOL4 | c.44+289G>A | Intron (SNP) | VAF 60/249 reads (24%) | catalogued as rs376470983; called by muse, mutect2, varscan2
- ARPP19P1 | n.155G>T | RNA (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- BCR | c.1279+17029G>T | Intron (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.7948A>T | RNA (SNP) | VAF 42/142 reads (30%) | catalogued as COSV61782071; called by muse, mutect2, varscan2
- DYNC1H1 | c.12902+48C>T | Intron (SNP) | VAF 111/492 reads (23%) | called by muse, mutect2, varscan2
- FAM124A | c.101-6064C>G | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- FAM20A | c.*2145G>A | 3'UTR (SNP) | VAF 113/367 reads (31%) | called by muse, mutect2, varscan2
- IGKV1D-27 | n.324C>A | RNA (SNP) | VAF 52/202 reads (26%) | called by muse, mutect2, varscan2
- KRT80 | c.301-62C>A | Intron (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- LRPAP1 | chr4:3500391 G>A | 3'Flank (SNP) | VAF 26/83 reads (31%) | catalogued as rs368596497; called by muse, mutect2, varscan2
- NDUFA5 | c.66+609C>G | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2
- NUMA1 | c.5216+566_5216+579del | Intron (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- OTOA | c.1146+39G>A | Intron (SNP) | VAF 81/241 reads (34%) | called by muse, mutect2, varscan2
- RACK1 | c.889-211G>A | Intron (SNP) | VAF 40/136 reads (29%) | catalogued as rs889405721; called by muse, mutect2, varscan2
- SPATA21 | c.35-3642C>A | Intron (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- TIGD1 | c.*2597C>A | 3'UTR (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
